Somatic mutation profile of tumor specimen TCGA-13-0887-01A (aliquot TCGA-13-0887-01A-01W-0421-09) from TCGA case TCGA-13-0887, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 42.9 years (15,669 days).
Specimen TCGA-13-0887-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95b32528-67be-4425-b6d3-497fe08a3bab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0887-10A (Blood Derived Normal), aliquot TCGA-13-0887-10A-01W-0420-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c66c876e-9c8a-4b11-a58e-1ceba8110ddf

The open-access MAF lists 134 somatic variants for this specimen: 98 protein-altering or splice-affecting, 35 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 35, Nonsense Mutation 6, Splice Site 5, Frame Shift Del 4, Intron 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 58/98 reads (59%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.2099G>C p.G700A | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60682114; called by muse, mutect2
- ACSS3 | c.1577T>C p.L526S | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (1); PolyPhen probably damaging (0.986); catalogued as COSV104370531, COSV99698681; called by muse, mutect2
- ADAM20 | c.301G>C p.D101H | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99833669; called by muse, mutect2
- ADGRE2 | c.1966G>T p.A656S | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.939); catalogued as rs143530914, COSV59692232; called by muse, mutect2, varscan2
- ADGRG4 | c.7726G>C p.D2576H | Missense Mutation (SNP) | VAF 30/494 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV99797560; called by muse, mutect2
- ADI1 | c.430A>G p.K144E | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV59376458; called by muse, mutect2
- AHCTF1 | c.4337T>A p.L1446H (on ENST00000366508; = p.L1420H on NM_015446.5) | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.005); catalogued as COSV58247032; called by muse, mutect2, varscan2
- AKAP9 | c.9526G>T p.E3176* (on ENST00000359028; = p.E3152* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 42/84 reads (50%) | catalogued as COSV62341059; called by muse, mutect2, varscan2
- AOX1 | c.1141T>G p.L381V | Missense Mutation (SNP) | VAF 194/513 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as COSV65980613; called by muse, mutect2, varscan2
- ATP11B | c.1596G>T p.K532N | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV60026984; called by muse, mutect2, varscan2
- BCAT2 | c.245C>A p.P82H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60271975; called by muse, mutect2, varscan2
- BIN2 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 55/292 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs555115486, COSV57204345; called by muse, mutect2, varscan2
- BTRC | c.196C>T p.P66S (on ENST00000370187 / NM_033637.4; = p.P30S on NM_003939.5) | Missense Mutation (SNP) | VAF 45/245 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV64560693; called by muse, mutect2, varscan2
- C7orf57 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1317008462, COSV62362134; called by muse, mutect2, varscan2
- CCDC39 | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 54/196 reads (28%) | catalogued as COSV56480169; called by muse, mutect2, varscan2
- CCKBR | c.979G>C p.A327P | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58099503; called by muse, mutect2, varscan2
- CDH6 | c.125G>C p.G42A | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV54063755, COSV54065976; called by muse, mutect2, varscan2
- CEP350 | c.6620C>G p.P2207R | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV62599836; called by muse, mutect2, varscan2
- CHD1 | c.612G>T p.K204N | Missense Mutation (SNP) | VAF 92/108 reads (85%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV52338203; called by muse, mutect2, varscan2
- CHD1L | c.2616-1G>A p.X872_splice | Splice Site (SNP) | VAF 60/207 reads (29%) | catalogued as rs782291956, COSV63613113; called by muse, mutect2, varscan2
- CMYA5 | c.4565T>G p.V1522G | Missense Mutation (SNP) | VAF 166/371 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as rs746462149, COSV71404530; called by muse, mutect2, varscan2
- CNNM1 | c.1361C>A p.S454Y | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV100764023; called by muse, mutect2
- COL5A2 | c.4358G>A p.R1453Q | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); catalogued as rs149064715; ClinVar: uncertain significance; called by muse, mutect2
- CPZ | c.1444G>A p.E482K (on ENST00000360986 / NM_001014447.3; = p.E471K on NM_003652.3) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as rs771666220, COSV100249379; called by muse, mutect2, varscan2
- DOCK7 | c.353G>C p.R118T | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.216); catalogued as COSV51998703, COSV52008306; called by muse, mutect2, varscan2
- DUSP19 | c.532T>C p.S178P | Missense Mutation (SNP) | VAF 39/355 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.653); catalogued as COSV61192942; called by muse, mutect2, varscan2
- EFEMP1 | c.130G>T p.D44Y | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV62615354; called by muse, mutect2, varscan2
- EHMT2 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 102/124 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV64993621; called by muse, mutect2, varscan2
- EPC2 | c.1795G>T p.A599S | Missense Mutation (SNP) | VAF 102/222 reads (46%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.983); catalogued as COSV51541384; called by muse, mutect2, varscan2
- ETV7 | c.268C>A p.L90I | Missense Mutation (SNP) | VAF 85/117 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60316297, COSV60317125; called by muse, mutect2, varscan2
- GPR101 | c.231C>G p.D77E | Missense Mutation (SNP) | VAF 45/52 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53237825; called by muse, mutect2, varscan2
- GPT | c.232C>G p.P78A | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV99477918; called by muse, mutect2, varscan2
- HAS2 | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 74/443 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.689); catalogued as COSV58262532; called by muse, mutect2, varscan2
- HCAR2 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs775536264, COSV100186705; called by muse, mutect2, varscan2
- HGF | c.1609C>A p.P537T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.932); catalogued as COSV99738952; called by muse, mutect2, varscan2
- HUWE1 | c.9097-1G>T p.X3033_splice | Splice Site (SNP) | VAF 86/184 reads (47%) | catalogued as COSV53338064; called by muse, mutect2, varscan2
- IFT57 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52708608; called by muse, mutect2, varscan2
- IGLV2-11 | c.124A>T p.T42S | Missense Mutation (SNP) | VAF 267/333 reads (80%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.035); catalogued as rs1359791451; called by muse, mutect2, varscan2
- IPPK | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.58); PolyPhen benign (0.119); catalogued as rs150868938; called by muse, mutect2, varscan2
- IQUB | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 166/235 reads (71%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV61237877; called by muse, mutect2, varscan2
- IRGC | c.390C>A p.D130E | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as COSV54983276; called by muse, mutect2, varscan2
- ITPKB | c.2338G>A p.A780T | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV55258436; called by muse, mutect2, varscan2
- KAT6B | c.4118A>G p.E1373G | Missense Mutation (SNP) | VAF 102/213 reads (48%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.04); catalogued as rs373140884; called by muse, mutect2, varscan2
- KCNA2 | c.835G>C p.E279Q | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV60369352; called by muse, mutect2, varscan2
- LRBA | c.7372A>G p.I2458V | Missense Mutation (SNP) | VAF 42/54 reads (78%) | SIFT tolerated (0.21); PolyPhen benign (0.054); catalogued as rs754778401, COSV63951341; called by muse, mutect2, varscan2
- MED13L | c.6038C>T p.P2013L | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.583); catalogued as COSV99930604; called by muse, mutect2
- MOK | c.1091C>G p.S364C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as rs971063841, COSV51963723; called by muse, mutect2, varscan2
- MYLK | c.2282T>A p.L761H | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60606388; called by muse, mutect2, varscan2
- NAA20 | c.208T>C p.W70R | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV100131875; called by muse, mutect2, varscan2
- NEB | c.19706G>A p.G6569E | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV50850657; called by muse, mutect2, varscan2
- OGA | c.2692G>T p.E898* | Nonsense Mutation (SNP) | VAF 49/102 reads (48%) | catalogued as COSV63381176; called by muse, mutect2, varscan2
- PABPN1 | c.847G>A p.G283S | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.549); catalogued as COSV53729281; called by muse, mutect2, varscan2
- PAPPA2 | c.2709T>G p.C903W | Missense Mutation (SNP) | VAF 70/403 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62774754; called by muse, mutect2, varscan2
- PITPNM3 | c.1870C>T p.R624W | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1458059596, COSV52593693; called by muse, mutect2, varscan2
- POLR2B | c.2281A>T p.T761S | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV58899098; called by muse, mutect2, varscan2
- PRKCE | c.590A>C p.Q197P | Missense Mutation (SNP) | VAF 42/331 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV60314607; called by muse, mutect2, varscan2
- PRSS27 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 23/32 reads (72%) | catalogued as COSV100234628; called by muse, mutect2, varscan2
- PUM1 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1443162687, COSV99929152; called by muse, mutect2
- PWWP3B | c.1234A>T p.S412C | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV61798692; called by muse, mutect2, varscan2
- RALGAPA2 | c.2001A>T p.K667N | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52491634; called by muse, mutect2, varscan2
- RGL3 | c.452G>A p.W151* | Nonsense Mutation (SNP) | VAF 34/68 reads (50%) | catalogued as COSV62697386; called by muse, mutect2
- RIMS1 | c.3337A>T p.R1113W | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53444525; called by muse, mutect2, varscan2
- RIOK3 | c.1366A>C p.K456Q | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV59772396; called by muse, mutect2, varscan2
- RNASE11 | c.517A>T p.S173C | Missense Mutation (SNP) | VAF 79/172 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV60087333; called by muse, mutect2, varscan2
- RNF150 | c.868G>T p.V290F | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100154439; called by muse, mutect2, varscan2
- SDK2 | c.2440G>A p.A814T | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as rs147112459; called by muse, mutect2, varscan2
- SGSM3 | c.2014G>C p.E672Q | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV50651377; called by muse, varscan2
- SLC12A8 | c.97A>C p.M33L | Missense Mutation (SNP) | VAF 99/124 reads (80%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV58863935, COSV58864163; called by muse, mutect2, varscan2
- SLC15A1 | c.1097T>C p.V366A | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV64730392; called by muse, mutect2, varscan2
- SLC39A10 | c.1831G>T p.D611Y | Missense Mutation (SNP) | VAF 10/308 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100660796; called by muse, mutect2
- SLC39A10 | c.1832A>G p.D611G | Missense Mutation (SNP) | VAF 10/306 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as rs1461379947, COSV100660797; called by muse, mutect2
- SORCS2 | c.1777G>A p.G593S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61164950; called by muse, mutect2
- SORL1 | c.1397A>G p.N466S | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs377405996; called by muse, mutect2, varscan2
- ST7 | c.642A>T p.E214D | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.216); catalogued as COSV55381469; called by muse, mutect2, varscan2
- STK31 | c.1756A>G p.S586G | Missense Mutation (SNP) | VAF 34/232 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV63454605; called by muse, mutect2, varscan2
- STK33 | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 229/448 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.338); catalogued as rs199852553; called by muse, mutect2, varscan2
- SUPT3H | c.955C>G p.R319G (on ENST00000371460 / NM_181356.3; = p.R308G on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/497 reads (9%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as COSV100178613; called by muse, mutect2
- SYNM | c.1783G>A p.G595S | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV100153128; called by muse, mutect2
- THAP2 | c.11A>G p.N4S | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); catalogued as rs747178505, COSV57348169; called by muse, mutect2, varscan2
- TTN | c.26517G>C p.Q8839H (on ENST00000591111; = p.Q7912H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/362 reads (32%) | PolyPhen benign (0.382); catalogued as COSV59934752; called by muse, mutect2, varscan2
- TUBA4A | c.652G>C p.D218H | Missense Mutation (SNP) | VAF 72/361 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV50277811; called by muse, mutect2, varscan2
- UBL4B | c.191A>G p.N64S | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV61944243; called by muse, mutect2, varscan2
- UGT1A10 | c.111C>G p.H37Q | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV60833836; called by muse, mutect2, varscan2
- VWA5A | c.2023G>T p.G675C | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.408); catalogued as COSV100827987, COSV64412776; called by muse, mutect2
- ZNF266 | c.1173A>T p.R391S | Missense Mutation (SNP) | VAF 13/241 reads (5%) | SIFT tolerated (0.83); PolyPhen benign (0.009); catalogued as COSV100749462; called by muse, mutect2
- ZNF536 | c.183dup p.A62Rfs*184 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | catalogued as rs780280249; called by pindel, varscan2
- ZNF560 | c.2299C>T p.P767S | Missense Mutation (SNP) | VAF 15/200 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs1215510284, COSV100039186; called by muse, mutect2
- ZSCAN21 | c.594T>A p.D198E | Missense Mutation (SNP) | VAF 103/196 reads (53%) | SIFT tolerated (0.53); PolyPhen benign (0.023); catalogued as COSV52849676; called by muse, mutect2, varscan2
- ADGRV1 | c.1718_1763del p.G573Efs*11 | Frame Shift Del (DEL) | VAF 49/114 reads (43%) | called by mutect2, pindel
- ALMS1 | c.1674_1687del p.P560Dfs*9 | Frame Shift Del (DEL) | VAF 40/255 reads (16%) | called by mutect2, pindel, varscan2
- BNIP5 | c.1585_1603+16del p.X529_splice | Splice Site (DEL) | VAF 74/217 reads (34%) | called by mutect2, pindel, varscan2
- CACNA1C | c.3829-18_3839del p.X1277_splice | Splice Site (DEL) | VAF 6/23 reads (26%) | called by mutect2, pindel, varscan2
- KRT84 | c.724C>G p.L242V | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.84); PolyPhen benign (0.034); called by muse, mutect2
- NCOR1 | c.6839_6868del p.E2280_M2290delinsV | In Frame Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel
- PKD2L2 | c.651_661del p.D217Efs*9 | Frame Shift Del (DEL) | VAF 11/91 reads (12%) | called by mutect2, pindel, varscan2
- SCN1A | c.2411del p.N804Tfs*14 (on ENST00000303395 / NM_001202435.3; = p.N793Tfs*14 on NM_006920.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 38/114 reads (33%) | called by mutect2, pindel, varscan2
- SFXN3 | c.444-14_445del p.X148_splice | Splice Site (DEL) | VAF 9/58 reads (16%) | called by mutect2, pindel, varscan2
- ARHGEF16 | c.1095G>A p.E365= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV65681493; called by muse, mutect2, varscan2
- BCS1L | c.1249C>T p.L417= | Silent (SNP) | VAF 10/210 reads (5%) | catalogued as COSV99829273; called by muse, mutect2
- BHLHE40 | c.1200G>T p.L400= | Silent (SNP) | VAF 8/162 reads (5%) | catalogued as COSV99848341; called by muse, mutect2
- C12orf42 | c.639C>T p.A213= | Silent (SNP) | VAF 21/30 reads (70%) | catalogued as rs919261657, COSV59380129; called by muse, mutect2, varscan2
- CD180 | c.303T>C p.H101= | Silent (SNP) | VAF 86/630 reads (14%) | catalogued as COSV56517202; called by muse, mutect2, varscan2
- CTNND2 | c.588A>G p.R196= | Silent (SNP) | VAF 40/107 reads (37%) | catalogued as COSV58872302; called by muse, mutect2, varscan2
- EGFLAM | c.2430C>T p.C810= | Silent (SNP) | VAF 34/64 reads (53%) | catalogued as COSV59295459; called by muse, mutect2, varscan2
- FZD2 | c.1545G>A p.S515= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV59528351; called by mutect2, varscan2
- GALNTL5 | c.1077A>G p.G359= | Silent (SNP) | VAF 33/164 reads (20%) | catalogued as COSV67179537; called by muse, mutect2, varscan2
- KCNAB1 | c.189G>T p.L63= | Silent (SNP) | VAF 47/152 reads (31%) | catalogued as rs757856229, COSV67484634; called by muse, mutect2, varscan2
- KIF21A | c.2889A>G p.K963= (on ENST00000361418 / NM_001378440.1; = p.K950= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 214/482 reads (44%) | catalogued as rs1161324213, COSV62768490; called by muse, mutect2, varscan2
- KIF21B | c.3057C>G p.S1019= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV59754128; called by muse, mutect2, varscan2
- KIF21B | c.1974G>T p.R658= | Silent (SNP) | VAF 3/64 reads (5%) | catalogued as COSV100145352; called by muse, mutect2
- MED13L | c.6039C>T p.P2013= | Silent (SNP) | VAF 8/115 reads (7%) | catalogued as COSV99930603; called by muse, mutect2
- MYLK3 | c.2019C>T p.F673= | Silent (SNP) | VAF 34/86 reads (40%) | catalogued as rs373988254; called by muse, mutect2, varscan2
- NAA25 | c.522G>A p.L174= | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as rs774172762, COSV55702749, COSV55708015; called by muse, mutect2, varscan2
- NPNT | c.1029A>T p.P343= | Silent (SNP) | VAF 6/162 reads (4%) | called by muse, mutect2
- OR2T10 | c.129T>C p.I43= | Silent (SNP) | VAF 5/116 reads (4%) | catalogued as COSV100393870; called by muse, mutect2
- OR7E24 | c.369C>T p.V123= | Silent (SNP) | VAF 6/156 reads (4%) | catalogued as rs901575276, COSV101509702; called by muse, mutect2
- OR7G1 | c.843C>A p.V281= | Silent (SNP) | VAF 40/434 reads (9%) | catalogued as COSV53317294; called by muse, mutect2
- PCNX3 | c.3054C>T p.F1018= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1290161236, COSV63135315; called by muse, mutect2, varscan2
- PTPRK | c.3909T>A p.S1303= (on ENST00000368215 / NM_001291984.2; = p.S1304= on NM_002844.4) | Silent (SNP) | VAF 44/62 reads (71%) | catalogued as COSV63893078; called by muse, mutect2, varscan2
- SLC7A14 | c.72C>A p.S24= | Silent (SNP) | VAF 61/94 reads (65%) | catalogued as COSV51579207; called by muse, mutect2, varscan2
- SPATA31E1 | c.951C>A p.G317= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as rs201064219, COSV57790049; called by muse, mutect2
- STXBP3 | c.756G>C p.L252= | Silent (SNP) | VAF 94/215 reads (44%) | catalogued as COSV64181751; called by muse, mutect2, varscan2
- SYNE2 | c.19131T>G p.S6377= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV59942657; called by muse, mutect2, varscan2
- TARBP1 | c.3594T>C p.A1198= | Silent (SNP) | VAF 44/326 reads (13%) | catalogued as COSV50180030; called by muse, mutect2, varscan2
- TM2D1 | c.30T>G p.S10= | Silent (SNP) | VAF 17/28 reads (61%) | catalogued as COSV53905666; called by muse, mutect2, varscan2
- TMC2 | c.1782G>A p.T594= | Silent (SNP) | VAF 12/156 reads (8%) | catalogued as rs778734621, COSV62656595; called by muse, mutect2
- TNR | c.2745G>A p.V915= | Silent (SNP) | VAF 14/290 reads (5%) | catalogued as COSV99692245; called by muse, mutect2
- TRMT44 | c.1281C>T p.L427= | Silent (SNP) | VAF 14/219 reads (6%) | catalogued as rs748550324, COSV101077891; called by muse, mutect2
- UGT2B17 | c.588T>C p.P196= | Silent (SNP) | VAF 58/346 reads (17%) | catalogued as COSV58501049; called by muse, mutect2, varscan2
- ZMYND8 | c.1431C>T p.A477= (on ENST00000311275 / NM_001363741.2; = p.A497= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 83/168 reads (49%) | catalogued as COSV53684156, COSV53688089; called by muse, mutect2, varscan2
- ZNF521 | c.1725T>A p.L575= | Silent (SNP) | VAF 41/196 reads (21%) | catalogued as COSV64123652; called by muse, mutect2, varscan2
- ZNF804A | c.531T>A p.T177= | Silent (SNP) | VAF 83/294 reads (28%) | catalogued as COSV56439558; called by muse, mutect2, varscan2
- PIGK | c.987-6786G>C | Intron (SNP) | VAF 75/206 reads (36%) | called by muse, mutect2, varscan2
